Surgical pathology report (de-identified scan), TCGA case TCGA-DY-A1DF, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DY-A1DF-01A (Primary Tumor).

150-0-5
Adenocarcinoma, NOS 8140/3
Site Code: Rectosigmoid C19.9
1/10/11
luw

(First Tumor)

Tumor Site:	Rectosigmoid Junction		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	None		
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☒ Expansile	☐ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☒ No	☐ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0		
Pathologist Comment:			

Source: NCI Genomic Data Commons file b2031878-267e-43f9-bf7e-19a06e38068f (TCGA-DY-A1DF.71175614-327E-4309-85A3-016B0C779D3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).